Somatic mutation profile of tumor specimen TCGA-IG-A7DP-01A (aliquot TCGA-IG-A7DP-01A-31D-A33E-09) from TCGA case TCGA-IG-A7DP, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 50.3 years (18,364 days).
Specimen TCGA-IG-A7DP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fdc82ccd-e540-42c2-a3e1-63b8b11114bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IG-A7DP-10A (Blood Derived Normal), aliquot TCGA-IG-A7DP-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17f19dcd-7e50-4620-b66d-242fc7f5c44e

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 5'UTR 1, Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FMR1 | c.359C>A p.P120H | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); called by muse, mutect2
- CNTNAP3 | c.2430C>T p.H810= | Silent (SNP) | VAF 7/90 reads (8%) | catalogued as rs1311386801; called by muse, mutect2
- SELENOI | c.-39G>T | 5'UTR (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2
